Surgical pathology report (de-identified scan), TCGA case TCGA-09-0367, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-0367-01A (Primary Tumor).

[page 1 of 4]
A. Momentum

B: Right ovary and tube (FS)

C: Uterus, cervix, left ovary and tube, rectosigmoid colon

H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1

F: Transverse colon tumor

F: Small bowel mesentery

G: Bladder peritoneum

A. Omentum, omentectomy: Papillary serous carcinoma, high grade.

C. Uterus, cervix, left ovary and fallopian tube, rectosigmoid colon: left salpingo-oophorectomy, total abdominal hysterectomy and rectosigmoidectomy:

- Cervix: No significant pathologic abnormality.
- Endometrium: Inactive pattern.
- Myometrium: Extensive papillary serous carcinoma, high grade, present on serosal surface with extensive lymphovascular invasion
- Left ovary: Ovarian parenchyma essentially replaced by papillary serous carcinoma, high grade.
- Fallopian tube: Extensive serosal involvement by papillary serous carcinoma, high grade, unremarkable fallopian mucosa.
- Rectosigmoid colon: Extensive serosal involvement by papillary serous carcinoma, high grade, with extension into muscularis propria, unremarkable colonic mucosa.

[page 2 of 4]
E. Transverse colon, "tumor," biopsy: Papillary serous carcinoma, high grade, in fibroadipose tissue.
F. Small bowel mesentery, biopsy: Papillary serous carcinoma, high grade.
G. Bladder peritoneum, biopsy: Papillary serous carcinoma, high grade, in fibrous tissue.

Note: Ovarian Tumor Synoptic Comment

- 1. Type of tumor: Papillary serous carcinoma.
- 2. Grade of tumor: III.
- 3. Location of tumor: Bilateral ovaries, omentum, with extensive serosal and lymphovascular invasion of myometrium.
- 4. Diameter of tumor: Present as multiple large masses, ranging up to 11.0 cm in the right ovary.
- 5. Appearance of surface of ovary: Bilateral ovaries essentially replaced by tumor, right greater than left.
- 6. Condition of capsule: Disrupted.
- 7. Appearance of cut surface: Numerous whorls of tan-white tumor.
- 8. Color of solid areas: Tan-white.
- 9. Necrosis: Absent.
- 10. Lymphatic/vascular invasion: Extensive.
- 11. Sites of metastases in pelvis: Ovary, uterus, bilateral fallopian tubes, rectum, urinary bladder, peritoneum.
- 12. Pelvic lymph nodes: None sampled.
- 13. Sites of metastases in abdomen: Omentum and large bowel.
- 14. Para-aortic lymph nodes: None sampled.
- 15. Peritoneal cytology: None submitted.
- 16. Other significant findings: None.
- 17. FIGO stage: IIIC.
- 18. TNM stage: pT3cNXM0.

Intraoperative Consult Diagnosis

FS1 (B) Ovary, right, oophorectomy: Carcinoma, consistent with ovarian primary, probably serous. (Dr.)

Clinical History

This is a , G3 P3, with ascites, omental caking and a complex right ovarian mass, positive peritoneal cytology and an elevated CA125 (2802) who undergoes right oophorectomy and tumor debulking with resectosigmoid resection, endo-colostomy and Hartmann's pouch/omentectomy, exploratory laparotomy, TAH/BSO and radical pelvic dissection.

Gross Description

The specimen is received in seven parts, labeled with the patient's name and medical record number. Parts A and B are received fresh. Parts C-F are received in formalin.

[page 3 of 4]
[REDACTED]

Part A, additionally labeled "omentum," consists of a section of red-tan, fibrofatty and firm tissue measuring 13.0 x 13.0 x 2.0 cm. The specimen is studded with multiple yellow-tan to yellow-white nodules ranging in size from 0.2 cm up to 2.5 cm in greatest dimension. A 1.0 x 1.0 x 1.0 cm portion of the specimen is taken for tumor banking, and representative sections are submitted in cassettes A1-A2.

Part B, additionally labeled "right ovary plus tube," consists of a partially cystic, partially solid structure with no identifiable ovary and attached fallopian tube, which measures 11.0 x 9.0 x 4.0 cm and weighs 238.2 gm. The cystic portion measures 4.0 cm in greatest dimension and has a cyst wall that ranges between 0.1 and 0.2 cm in greatest dimension, and has two exophytic papillary-like structures on the external surface, which measure 2.0 and 0.8 cm in greatest dimension, respectively. Deep to these, the specimen is solid and has a fleshy, yellow-tan, irregular parenchyma. The solid portion measures 4.0 x 3.0 x 2.0 cm. The attached fallopian tube measures 3.5 cm in length x 0.4 cm in average diameter, is smooth, pink-tan, and otherwise unremarkable. The external surface of the specimen is inked in black. A representative section of the solid portion is submitted as frozen section 1 with the remnant in cassette B1. The remainder of the specimen is submitted as follows:

Cassette B2: Representative sections of fallopian tube.

Cassette B3: Representative sections of larger mass on exterior surface of cyst.

Cassette B4: Representative sections of smaller exophytic mass on external surface of cyst.

Cassettes B5-B6: Additional representative sections of cyst.

Cassettes B7-B10: Representative sections of solid portion of cyst.

Part C, labeled "uterus, cervix, left ovary and tube and rectosigmoid colon," consists of a uterus, attached cervix, fallopian tube and attached soft tissue tumor mass, and attached short segment of sigmoid colon. The uterine specimen measures 7.5 cm from superior to inferior, 5.5 cm from cornu to cornu and 4.0 cm from anterior to posterior. The cervix measures 3.5 cm from side to side, 3.0 cm from anterior to posterior and approximately 2.0 cm in length. The serosal surface of the uterus is tan-brown, smooth and glistening, with areas of subserosal hemorrhage scattered throughout. The cervical mucosa is tan-white, smooth and glistening, again with small areas of punctate mucosal and submucosal hemorrhage. The specimen probes to 6.5 cm and is opened along the lateral surfaces. The endocervical mucosa is pale tan and measures 1.0 mm in thickness. The endometrium is also pale tan, and free of polyps and masses. The endometrium measures 2.0 mm in thickness. The myometrium is serially sectioned, revealing no mural lesions. The myometrium averages 1.3 cm in thickness. Two nodular masses of tissue are attached to the left surface of the uterus. The serosal surfaces of both are similar, each with a very nodular contour, covered by a tan-brown serosa, and grossly obvious tumor nodules. Grossly, it is difficult to ascertain which of these two masses contains the ovary, however one does appear to be attached to the uterus by a tubular structure, likely the fallopian tube. This portion of tissue measures 7.5 x 4.5 x 4.0 cm and the adjacent tubular structure measures 2.5 cm in length, with an average diameter of 1.0 cm. Serial sections through the mass reveal no grossly obvious ovarian tissue, though a lumen filled with necrotic tissue is identified in the previously-described tubular structure. The adjacent mass of tissue has a similar gross appearance and measures 5.5 x 4.5 x 3.5 cm. One portion of the specimen contains a thin-walled cyst filled with translucent fluid, measuring 3.0 cm in greatest diameter. On cut section, the specimen is composed of multiple nodules of tan-white, firm tissue ranging in size between 0.5 and 2.0 cm. Adherent to the uterus and ovary is a segment of large bowel measuring 14.0 cm in length with an average diameter of 4.0 cm. The serosal surface is diffusely caked with tumor nodules ranging in size between 0.2 and 0.5 cm, though with confluence of tumor in other areas. What is thought to be the proximal margin is received stapled shut, with the distal margin remaining open. Upon opening, a scant, tan-brown mucoid material is identified. The mucosa is pale tan, and unremarkable. Sections are submitted as follows:

Cassette C1: Anterior cervix.

Cassette C2: Posterior cervix.

Cassette C3: Anterior endomyometrium.

Cassette C4: Posterior endomyometrium.

Cassettes C5-C6: Sections of putative ovary.

[page 4 of 4]
Cassette C7: Putative fallopian tube.
Cassettes C8-C9: Mass adjacent to ovary.
Cassette C10: Proximal bowel margin.
Cassette C11: Distal bowel margin.
Cassette C12: Sections through unremarkable bowel mucosa.
Cassette C13: Representative sections of small bowel serosa.

Part D, labeled " rectum, staples proximal," consists of a single, short segment of rectum measuring 6.5 cm in length with an average diameter of 2.5 cm. Attached to the specimen is a large amount of very irregular and fragmented brown-tan, fibrous connective tissue measuring 8.5 cm in width x 4.0 x 2.5 cm. The surrounding soft tissue is inked prior to opening of the staple surface at the proximal margin. The specimen is opened to reveal pale tan-brown, glistening mucosa with no grossly identifiable masses or lesions. A section of the proximal margin is submitted in cassette D1. A section of the distal margin is submitted in cassette D2. A random section is submitted in cassette D3. The attached fibrous connective tissue is serially sectioned, revealing a pericolonic mass of tan-white tumor measuring 3.0 x 2.5 x 2.0 cm. The tumor mass approaches the proximal margin of resection within 1.0-2.0 mm, and the lateral margin of resection within 3.0 mm. A representative section is submitted in cassette D4.

Part E, labeled "transverse colon tumor," consists of an irregular and fragmentary tan-brown, polypoid mass measuring 3.4 x 2.0 x 1.5 cm. The specimen is serially sectioned, and representative sections are submitted in cassette E1.

Part F, labeled "small bowel mesentery," consists of a single ovoid nodule of yellow-tan, soft tissue measuring 0.6 x 0.5 x 0.2 cm. The specimen is entirely submitted in cassette F1.

Part G, labeled "bladder peritoneum," consists of an irregular and fragmentary tan-brown, polypoid mass measuring 3.4 x 1.8 x 1.0 cm. The specimen is serially sectioned, and representative sections are submitted in cassette G1.

Fee Codes:

1

Source: NCI Genomic Data Commons file 8cd0a5cf-1c31-4791-a74c-974b62429c12 (TCGA-09-0367.8A24FE8A-9F7F-4FBF-86C7-704427CCAF89.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).